Gene-level copy-number profile of tumor specimen HCM-CSHL-0584-C19-06A from HCMI case HCM-CSHL-0584-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 58.7 years (21,437 days).
Specimen HCM-CSHL-0584-C19-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 02cbd273-7e07-431e-9b31-9b96e059c2d6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0584-C19-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/7c867d2a-f381-4385-84c1-77b3b7a51880

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 43; copy number 2: 5,564; copy number 3: 157; copy number 4: 29,480; copy number 5: 1,084; copy number 6: 14,698; copy number 7: 402; copy number 8: 5,329; copy number 9: 315; copy number 10: 220; copy number 11: 48; copy number 12: 762; copy number 13: 203; copy number 16: 14; copy number 48: 7; copy number 56: 21.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–5): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr3:151,814,073–151,828,488, 1 gene (within-gene range 0–6): AADAC.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:39,816,542–40,106,661, 1 gene (within-gene range 0–1): FGF7P3.
- chr9:39,886,861–40,153,147, 9 genes: RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr9:41,310,816–41,573,606, 5 genes: AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,590 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:195,614,947–195,620,233, 1 gene, copy number 10: MUC20P1.
- chr7:38,239,580–38,249,572, 1 gene, copy number 9: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 9: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr8:38,400,215–38,468,834, 1 gene, copy number 16 (within-gene range 5–16): FGFR1.
- chr8:38,421,889–38,601,200, 5 genes, copy number 16: AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1.
- chr13:54,938,604–55,174,548, 4 genes, copy number 12: AL390964.1, LINC02335, AL139038.1, MIR5007.
- chr13:67,790,407–78,617,328, 115 genes, copy number 12 (within-gene range 8–12) (broad region; genes not listed).
- chr13:103,043,998–114,337,626, 154 genes, copy number 9 (broad region; genes not listed).
- chr14:104,579,764–104,590,515, 2 genes, copy number 9 (within-gene range 6–9): C14orf180, BX927359.1.
- chr15:53,513,741–56,629,592, 44 genes, copy number 9–11: WDR72, RNU2-53P, RNU6-449P, AC084759.1, AC084759.3, AC084759.2, UNC13C, AC010867.1, HNRNPA1P74, AC025272.1, AC011912.1, RSL24D1, RAB27A, AC018926.2, PIGBOS1, PIGB, CCPG1, AC018926.1, AC018926.3, DNAAF4-CCPG1, MIR628, C15orf65, DNAAF4, AC013355.1, PYGO1, AC012378.2, PRTG, AC012378.1, AC009997.1, NEDD4, CNOT6LP1, RN7SL568P, CD24P2, RFX7, AC084783.1, TEX9, AC068726.1, RNU6-1287P, HMGB1P33, AC084782.1, AC084782.2, MNS1, AC084782.3, AC090518.1.
- chr15:88,797,413–94,550,572, 167 genes, copy number 9–13 (broad region; genes not listed).
- chr16:28,659,696–30,822,110, 176 genes, copy number 13 (broad region; genes not listed).
- chr16:32,388,135–32,678,831, 13 genes, copy number 12: AC138915.2, PABPC1P13, AC138915.3, AC138915.1, ABCD1P3, AC137800.1, AC137800.2, AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3.
- chr19:4,292,232–4,540,067, 23 genes, copy number 12 (within-gene range 8–12): TMIGD2, FSD1, STAP2, AC104521.1, MPND, AC007292.3, EIF1P6, AC007292.2, SH3GL1, AC007292.1, CHAF1A, AC011498.3, UBXN6, MIR4746, AC011498.2, AC011498.7, AC011498.6, AC011498.1, HDGFL2, PLIN4, PLIN5, AC011498.4, LRG1.
- chr19:29,001,670–29,015,160, 2 genes, copy number 9: RNA5SP470, LINC01532.
- chr20:30,294,550–64,327,972, 867 genes, copy number 9–56 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 43. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
